Gene-level copy-number profile of tumor specimen ALCH-AFFT-TTP1-A from ALCHEMIST case ALCH-AFFT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,124 days).
Specimen ALCH-AFFT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06477cf5-88a7-4afd-8551-181d699f7a81.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,865 have no estimate.
https://portal.gdc.cancer.gov/files/03446983-4466-43fd-85dd-c2dea5537e5e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 443; copy number 1: 19,733; copy number 2: 34,272; copy number 3: 2,248; copy number 4: 1,700; copy number 5: 313; copy number 6: 24; copy number 7: 2; copy number 8: 21; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,736,201, 10 genes (within-gene range 0–1): ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2.
- chr1:3,736,943–3,737,103, 1 gene (within-gene range 0–1): AL136528.1.
- chr2:141,208,082–141,208,376, 1 gene (within-gene range 0–2): RPS16P3.
- chr2:238,138,668–238,155,994, 2 genes: KLHL30, KLHL30-AS1.
- chr3:52,451,100–52,579,237, 5 genes (within-gene range 0–1): TNNC1, NISCH, STAB1, NT5DC2, SMIM4.
- chr3:52,551,846–52,560,707, 2 genes (within-gene range 0–1): RNU6-856P, RNU6ATAC16P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:57,120,796–57,122,624, 1 gene: AC034244.2.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr7:45,816,216–45,821,064, 3 genes: CICP20, AC096582.1, AC096582.2.
- chr8:12,178,697–12,182,719, 1 gene (within-gene range 0–10): ALG1L11P.
- chr8:33,473,386–33,523,291, 4 genes (within-gene range 0–1): TTI2, MAK16, SNORD13, AC091144.1.
- chr9:66,942,703–66,976,991, 3 genes: AL353770.4, AL353770.2, FAM74A3.
- chr9:135,663,322–135,666,422, 1 gene: LCN9.
- chr11:2,159,779–2,173,138, 3 genes (within-gene range 0–2): INS, TH, MIR4686.
- chr11:2,376,177–2,407,908, 3 genes (within-gene range 0–2): CD81, TSSC4, AC124057.1.
- chr11:50,032,874–50,102,898, 3 genes: OR4C45, OR4C49P, GTF2IP11.
- chr11:115,582,297–115,600,339, 1 gene: AP003174.1.
- chr14:104,137,150–104,180,894, 2 genes: AL359399.1, KIF26A.
- chr14:104,579,764–104,770,271, 10 genes (within-gene range 0–1): C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–2): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr18:7,134,931–7,301,153, 3 genes: SLC25A51P2, LRRC30, AP005270.1.
- chr18:11,326,270–11,670,165, 13 genes: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, AP001120.1.
- chr18:11,745,626–11,747,581, 1 gene (within-gene range 0–1): ASNSP6.
- chr21:42,843,094–42,879,568, 1 gene: WDR4.
- chr22:18,533,646–18,615,900, 5 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 362 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:73,787,370–75,611,116, 24 genes, copy number 5–6: AL591463.1, RNU4ATAC8P, LRRIQ3, FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3, AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1.
- chr1:86,346,824–87,453,373, 22 genes, copy number 5: ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1, CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140, LMO4, LINC01364, RNA5SP52.
- chr1:87,805,286–87,808,372, 1 gene, copy number 5: AL445437.1.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr8:12,182,096–12,194,133, 1 gene, copy number 10 (within-gene range 0–10): FAM86B1.
- chr9:22,646,200–38,069,227, 301 genes, copy number 5–8 (broad region; genes not listed).
- chr9:41,310,816–41,573,606, 5 genes, copy number 5–10: AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70.
- chr9:41,760,088–41,764,175, 1 gene, copy number 6: AL162731.1.
- chr9:64,810,865–64,836,341, 2 genes, copy number 6–7: BNIP3P4, AL359955.1.
- chr9:136,196,250–136,205,128, 1 gene, copy number 5: LHX3.
- chr11:112,967–139,612, 3 genes, copy number 7–8 (within-gene range 3–8): AC069287.1, CICP23, LINC01001.

Autosomal genes at a single copy (total copy number 1): 17,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
